Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6DY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6DY-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT PELVIC LYMPH NODES:
Six lymph nodes, no tumor present.
- (B) LEFT PELVIC LYMPH NODES:
Six lymph nodes, no tumor present.
- (C) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

path ICD-0-3
Adenocarcinoma 8140/3
c44F Adenocarcinoma, acinar 8140/3
Site Prostate NOS C61.9
JN 5/21/13

GROSS DESCRIPTION

- (A) RIGHT PELVIC LYMPH NODES - Multiple lymph nodes (0.4 x 0.4 x 0.3 to 6.0 x 1.2 x 0.8 cm). Four lymph nodes are submitted for frozen section.
SECTION CODE: A1, one lymph node bisected; A2, one lymph node bisected; A3, one lymph node; A4, one lymph node bisected; A5, one lymph node bisected; A6-A11, one lymph node serially sectioned.
*FS/DX: SIX LYMPH NODES, NO TUMOR PRESENT.
- (B) LEFT PELVIC LYMPH NODES - A tan-yellow irregular fragment of adipose tissue (4.5 x 3.5 x 1.5 cm). Six possible lymph nodes are found ranging in size from 0.4 x 0.4 x 0.2 cm to 2.8 x 1.4 x 0.5 cm.
SECTION CODE: B1, three possible lymph nodes; B2, two possible lymph nodes; B3, B4, one possible lymph node serially sectioned.
- (C) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (3+4). (SEE COMMENT)

TUMOR EXTENDING FOCALLY TO THE INKED MARGIN OF RESECTION (LESS THAN 1.0 MM).

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in the right lateral, right postero-lateral, right posterior, mid posterior, left posterior, left posterolateral, and left lateral peripheral zone. The tumor focus measures 3.5 x 1.0 cm in the largest cross-sectional dimension and it is present in the three cross sections of the prostate, extensively in the apex and focally in the base region. In the left posterior surface of the prostate, tumor extends focally (less than 1.0 mm) to the inked margin of resection. No extraprostatic tissue is present at the site of the positive margin to evaluate the possible presence of extraprostatic extension.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles, and attached segments of right and left vasa deferentia.

The prostate gland (5.1 x 4.5 x 5.7 cm, 95 grams, post fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A palpable nodule is present in the right posterolateral aspect of the prostate in the mid region. A well circumscribed nodule (3.3 x 3.0 x 3.0 cm) protrudes from the base of the prostate around the urethra. Serial cross sections after fixation demonstrate a firm area in the right peripheral zone of the second and third cross sections.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1-C4, right seminal vesicle and segment of right vas deferens from the base towards the tip; B5-B7, left seminal vesicle and segment of left vas deferens from the base towards the tip; C8, C9, median lobe; C10, C11, prostatic base right border; C12-C14, prostatic base right posterior border; C15-C21, prostatic base central portion posterior aspect from right to left; C22-C27, prostatic base central portion, anterior aspect, alternating sections from right to left; C28 - C33, prostatic base left border; C34, see diagram; C35-C37, prostatic base left posterior border; C38-C40, apex anterior; C41, C42, apex left; C43-C45, apex posterior; C46, C47, apex right; C48, detached portions of margin of resection according to specimen radiograph; C49-C60, sections of the three cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow, and posterior surface in black. Blue ink (C1, 2, 5, 6, 12, 13, 15-21, 34-36, 43-45) and orange ink (C50, 51, 54-56, 60) denote surfaces which do not represent the true margin of resection.

SNOMED CODES

[page 3 of 3]
[REDACTED]
[REDACTED]
Specimen Date/Time:
[REDACTED]

Released by:

-----END OF REPORT-----

HL/AL Discrepancy		

hw 5/14/13

5/14/13

Source: NCI Genomic Data Commons file ef2eb550-fde8-476a-a6ad-b8606907c29d (TCGA-KK-A6DY.3C4C5AAE-6F27-4ECE-8F72-91DC9EF477C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).